Somatic mutation profile of cancer-model specimen HCM-SANG-0291-C15-85A (3D Organoid; aliquot HCM-SANG-0291-C15-85A-01D-A78M-36), derived from the primary tumor of HCMI case HCM-SANG-0291-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G1.
Specimen HCM-SANG-0291-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e698fe2d-61c4-4553-9552-b6b17935dbe7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0291-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0291-C15-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21d643da-e66a-4199-984f-30ecb7b141c7

The open-access MAF lists 181 somatic variants for this specimen: 116 protein-altering or splice-affecting, 44 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 44, Intron 9, Nonsense Mutation 6, RNA 5, 5'UTR 4, Frame Shift Ins 3, 5'Flank 3, Splice Site 3, Splice Region 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 53/71 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 168/169 reads (99%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANK2 | c.2513C>T p.T838M | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779991081, COSV52163065; called by muse, mutect2, varscan2
- ARHGAP22 | c.1562C>T p.S521L | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1299976791, COSV99984325; called by muse, mutect2, varscan2
- ATP13A3 | c.2109G>T p.Q703H | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV55463223; called by muse, mutect2, varscan2
- BAAT | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 216/321 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200347226, COSV52287019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC42BPA | c.2884G>A p.D962N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as rs373478290; called by muse, mutect2, varscan2
- CHST15 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs748902428, COSV60564798; called by muse, mutect2
- CLIP3 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs765940705; called by muse, mutect2, varscan2
- COL5A1 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 173/561 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as rs774936702, COSV65665617; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD3 | c.10402G>T p.A3468S (on ENST00000297405 / NM_001363185.1; = p.A3299S on NM_052900.3) | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV99848017, COSV99848047; called by muse, mutect2, varscan2
- DLG2 | c.848A>C p.Y283S | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.491); catalogued as rs1473853552; called by muse, mutect2, varscan2
- DLL4 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 121/280 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1357715175; called by muse, mutect2, varscan2
- FAM53B | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs543830628, COSV55101966; called by muse, mutect2, varscan2
- FMN2 | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); catalogued as rs370099468; called by muse, varscan2
- FTMT | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); catalogued as rs773586422, COSV58420603; called by muse, mutect2, varscan2
- GABRG2 | c.1202G>T p.S401I (on ENST00000361925 / NM_001375343.1; = p.S361I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 217/475 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100729797; called by muse, mutect2, varscan2
- GNAS | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 421/832 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs753610380; called by muse, mutect2, varscan2
- HAL | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 237/525 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.945); catalogued as rs777578144; called by muse, mutect2, varscan2
- HFE | c.119A>G p.Q40R | Missense Mutation (SNP) | VAF 113/246 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs752497474; called by muse, mutect2, varscan2
- ITIH5 | c.2083G>A p.V695M | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as rs529570147; called by muse, mutect2, varscan2
- KCNT1 | c.1387G>A p.A463T (on ENST00000488444; = p.A482T on NM_020822.3) | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs577633745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA1 | c.5012T>G p.I1671S | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV101056657; called by muse, mutect2
- LRP1B | c.11764A>G p.R3922G | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV67200355; called by muse, mutect2, varscan2
- LRP1B | c.4726C>A p.L1576I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1168207303, COSV67191549, COSV67202130; called by muse, mutect2, varscan2
- LRRIQ3 | c.1395dup p.Y466Ifs*8 | Frame Shift Ins (INS) | VAF 42/104 reads (40%) | catalogued as rs1456074613; called by mutect2, pindel, varscan2
- MCRS1 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs775135641, COSV57792907; called by muse, mutect2, varscan2
- NOTCH3 | c.6700C>T p.R2234C | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as rs184996545; called by muse, mutect2, varscan2
- OVCH1 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 34/77 reads (44%) | catalogued as rs200302819; called by muse, mutect2, varscan2
- PCDH15 | c.4352T>C p.L1451P | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs748019624, COSV100230018; called by muse, varscan2
- PCDHB5 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 287/618 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1477706225; called by muse, mutect2, varscan2
- PCDHGA7 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 94/223 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV53961402; called by muse, mutect2, varscan2
- PKHD1L1 | c.4658C>A p.S1553* | Nonsense Mutation (SNP) | VAF 79/177 reads (45%) | catalogued as rs372148502, COSV101005104; called by muse, mutect2, varscan2
- PLOD2 | c.1132T>G p.F378V | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV51468525, COSV99282387; called by muse, mutect2, varscan2
- PRB2 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs759081917; called by muse, mutect2, varscan2
- PTPRT | c.2504G>A p.R835H | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs373191879, COSV61981995; called by muse, mutect2, varscan2
- PXDN | c.1709A>C p.K570T | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53232567; called by muse, mutect2, varscan2
- RNF6 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 90/225 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV60417657; called by muse, mutect2, varscan2
- SCTR | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1342136350; called by muse, mutect2, varscan2
- SLC11A1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs769490777, COSV99261941; called by muse, mutect2, varscan2
- SLC7A4 | c.1723C>G p.L575V | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.479); catalogued as rs750996417; called by muse, mutect2, varscan2
- SPEN | c.5092G>A p.E1698K | Missense Mutation (SNP) | VAF 148/302 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV65365791; called by muse, mutect2, varscan2
- STK32B | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs754708470, COSV51483857; called by muse, mutect2, varscan2
- SYNE1 | c.7388T>G p.L2463R (on ENST00000367255 / NM_182961.4; = p.L2470R on NM_033071.3) | Missense Mutation (SNP) | VAF 155/341 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs746315899, COSV55009053, COSV55030061; called by muse, mutect2, varscan2
- TCF15 | c.467A>C p.D156A | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55720559; called by muse, mutect2, varscan2
- TLR8 | c.1991C>T p.A664V (on ENST00000218032 / NM_138636.5; = p.A682V on NM_016610.4) | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT tolerated (0.57); PolyPhen benign (0.136); catalogued as rs148772263, COSV54318763; called by muse, mutect2, varscan2
- TPTE | c.11+1G>A p.X4_splice | Splice Site (SNP) | VAF 67/278 reads (24%) | catalogued as rs764824040; called by muse, mutect2, varscan2
- UNC13A | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 242/503 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs752809538; called by muse, mutect2, varscan2
- USP8 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 123/210 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.142); catalogued as rs759699181; called by muse, mutect2, varscan2
- ZSCAN18 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.028); catalogued as rs1293804277; called by muse, mutect2
- AASDH | c.1627T>G p.L543V | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT tolerated (0.53); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- AATK | c.2710G>A p.D904N (on ENST00000326724 / NM_001080395.3; = p.D801N on NM_004920.2) | Missense Mutation (SNP) | VAF 86/169 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ABCB4 | c.1596G>T p.Q532H | Missense Mutation (SNP) | VAF 181/338 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- AKAP6 | c.6608T>C p.L2203P | Missense Mutation (SNP) | VAF 95/184 reads (52%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- AMPH | c.1216-1G>T p.X406_splice | Splice Site (SNP) | VAF 31/98 reads (32%) | called by muse, mutect2, varscan2
- ARID1A | c.2396dup p.Q802Sfs*15 | Frame Shift Ins (INS) | VAF 39/116 reads (34%) | called by mutect2, pindel, varscan2
- ATP2B2 | c.397+2T>A p.X133_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- ATP8B3 | c.2129G>A p.W710* | Nonsense Mutation (SNP) | VAF 12/342 reads (4%) | called by muse, mutect2
- AUTS2 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 126/250 reads (50%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CARS1 | c.207-8T>G | Splice Region (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- CCDC81 | c.949G>A p.D317N (on ENST00000445632 / NM_001156474.2; = p.D227N on NM_021827.4) | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CDYL2 | c.882C>A p.D294E | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CKAP5 | c.4427C>G p.A1476G | Missense Mutation (SNP) | VAF 61/61 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CNGA3 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 123/250 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- COX7B2 | c.218T>G p.V73G | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CPXM2 | c.1701G>T p.R567S | Missense Mutation (SNP) | VAF 92/196 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- DEFB110 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENDOV | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- EYS | c.862+4A>C | Splice Region (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- FAM186A | c.4960G>A p.V1654I | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.035); called by muse, varscan2
- FCRL4 | c.431C>A p.S144Y | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- GJB7 | c.77C>A p.A26D | Missense Mutation (SNP) | VAF 97/191 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- H2AC8 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 83/167 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC3 | c.398T>G p.L133R | Missense Mutation (SNP) | VAF 105/204 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIC1 | c.1292G>A p.S431N (on ENST00000322941 / NM_001098202.1; = p.S412N on NM_006497.4) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- KCNA3 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAMA4 | c.3969-8T>A | Splice Region (SNP) | VAF 75/155 reads (48%) | called by muse, mutect2, varscan2
- LRP1B | c.6875C>A p.S2292Y | Missense Mutation (SNP) | VAF 94/194 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- LRP8 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 289/532 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- LRRC49 | c.1947G>T p.L649F | Missense Mutation (SNP) | VAF 109/329 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- LRRC74A | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 110/238 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYST | c.8578G>T p.A2860S | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K13 | c.1196_1198del p.S399del | In Frame Del (DEL) | VAF 39/97 reads (40%) | called by pindel, varscan2
- MAP7D3 | c.587T>C p.L196S | Missense Mutation (SNP) | VAF 52/54 reads (96%) | SIFT tolerated (0.11); PolyPhen benign (0.09); called by muse, varscan2
- MIA3 | c.2087C>G p.A696G | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- MTUS2 | c.2196T>G p.F732L | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NBEA | c.3362dup p.N1121Kfs*2 | Frame Shift Ins (INS) | VAF 25/72 reads (35%) | called by mutect2, varscan2
- NOX5 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 168/586 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- OASL | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 97/182 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- OGFRL1 | c.827A>C p.K276T | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- OR1B1 | c.298T>G p.L100V | Missense Mutation (SNP) | VAF 184/311 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR51A7 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR6K6 | c.605T>C p.I202T (on ENST00000368144; = p.I178T on NM_001005184.1) | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCLO | c.2282A>G p.K761R | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- POTEB3 | c.1529C>A p.S510Y | Missense Mutation (SNP) | VAF 68/457 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- POU4F3 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 193/418 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKACA | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 69/320 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PRKACB | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRKD1 | c.1619T>G p.L540R | Missense Mutation (SNP) | VAF 159/318 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RAB5A | c.222G>A p.W74* | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- RFWD3 | c.2159A>G p.D720G | Missense Mutation (SNP) | VAF 103/205 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SERPINI2 | c.591C>A p.D197E | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SHANK1 | c.5293A>T p.S1765C | Missense Mutation (SNP) | VAF 152/283 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SLC22A23 | c.1277A>C p.N426T | Missense Mutation (SNP) | VAF 96/206 reads (47%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ST6GALNAC5 | c.818A>G p.E273G | Missense Mutation (SNP) | VAF 39/197 reads (20%) | PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- STXBP5L | c.2597C>T p.S866F | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.873); called by muse, mutect2
- SUPT6H | c.2101C>T p.Q701* | Nonsense Mutation (SNP) | VAF 18/278 reads (6%) | called by muse, mutect2
- TFG | c.547T>C p.S183P | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TMEM132C | c.2147A>G p.Q716R | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UACA | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- USH2A | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP17L7 | c.617A>C p.K206T | Missense Mutation (SNP) | VAF 269/795 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- VIM | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 122/263 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- WDFY4 | c.3764T>G p.L1255R | Missense Mutation (SNP) | VAF 104/210 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- XRN2 | c.2576T>G p.L859R | Missense Mutation (SNP) | VAF 74/136 reads (54%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZFPL1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 32/417 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AARD | c.150C>T p.L50= | Silent (SNP) | VAF 205/425 reads (48%) | catalogued as rs753102875, COSV65599803; called by muse, mutect2, varscan2
- AASDH | c.3096C>T p.G1032= | Silent (SNP) | VAF 106/212 reads (50%) | catalogued as rs1204475686; called by muse, mutect2, varscan2
- ARNT | c.1116C>T p.I372= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as rs1177448013; called by muse, mutect2, varscan2
- C7orf26 | c.999G>A p.A333= | Silent (SNP) | VAF 77/179 reads (43%) | catalogued as rs766481174; called by muse, mutect2, varscan2
- CD8A | c.489G>A p.A163= | Silent (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- DTL | c.1092G>A p.T364= | Silent (SNP) | VAF 69/177 reads (39%) | catalogued as rs530685779, COSV65343426; called by muse, mutect2, varscan2
- FLG | c.2175T>C p.T725= | Silent (SNP) | VAF 275/521 reads (53%) | called by muse, mutect2, varscan2
- FSIP2 | c.1512T>G p.T504= | Silent (SNP) | VAF 14/24 reads (58%) | called by mutect2, varscan2
- GNAL | c.315G>A p.P105= (on ENST00000269162 / NM_001142339.3; = p.P182= on NM_182978.4) | Silent (SNP) | VAF 83/183 reads (45%) | catalogued as rs746681260, COSV52324604; called by muse, mutect2, varscan2
- GNB2 | c.63C>T p.A21= | Silent (SNP) | VAF 108/244 reads (44%) | catalogued as rs1173434349; called by muse, mutect2, varscan2
- GRB7 | c.1404C>A p.V468= | Silent (SNP) | VAF 191/1579 reads (12%) | catalogued as COSV100485338; called by muse, mutect2, varscan2
- GRIK1 | c.975C>T p.Y325= | Silent (SNP) | VAF 94/94 reads (100%) | catalogued as rs377352111; called by muse, mutect2, varscan2
- HDLBP | c.351G>T p.L117= | Silent (SNP) | VAF 135/300 reads (45%) | called by muse, mutect2, varscan2
- KANK4 | c.2940T>G p.A980= | Silent (SNP) | VAF 77/179 reads (43%) | called by muse, mutect2, varscan2
- KCNC1 | c.15C>T p.D5= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs1487238241, COSV56391697; called by muse, varscan2
- KCNV1 | c.1240T>C p.L414= | Silent (SNP) | VAF 82/147 reads (56%) | called by muse, mutect2, varscan2
- KCNV1 | c.492T>G p.T164= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV52087520; called by muse, mutect2, varscan2
- KHDRBS2 | c.762A>G p.P254= | Silent (SNP) | VAF 48/90 reads (53%) | called by muse, mutect2, varscan2
- KRT222 | c.90G>A p.R30= | Silent (SNP) | VAF 72/488 reads (15%) | called by muse, mutect2, varscan2
- LOXHD1 | c.2254C>T p.L752= | Silent (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2
- MAB21L4 | c.351G>A p.G117= | Silent (SNP) | VAF 24/377 reads (6%) | called by muse, mutect2
- MYO1E | c.2508C>T p.L836= | Silent (SNP) | VAF 109/187 reads (58%) | called by muse, mutect2, varscan2
- PCDHA12 | c.213C>T p.H71= | Silent (SNP) | VAF 258/672 reads (38%) | catalogued as rs563250653, COSV56530222; called by muse, varscan2
- PDCD4 | c.234C>T p.S78= | Silent (SNP) | VAF 97/226 reads (43%) | catalogued as rs1022370581; called by muse, mutect2, varscan2
- PSEN1 | c.369G>A p.E123= | Silent (SNP) | VAF 96/183 reads (52%) | called by muse, mutect2, varscan2
- RBM5 | c.426C>T p.F142= | Silent (SNP) | VAF 67/132 reads (51%) | called by muse, mutect2, varscan2
- RNF180 | c.805T>C p.L269= | Silent (SNP) | VAF 62/146 reads (42%) | catalogued as rs762302870, COSV56961069; called by muse, mutect2, varscan2
- RNF40 | c.1503C>T p.A501= | Silent (SNP) | VAF 113/295 reads (38%) | called by muse, mutect2, varscan2
- RTF2 | c.351G>A p.A117= | Silent (SNP) | VAF 107/246 reads (43%) | catalogued as rs375446899; called by muse, mutect2, varscan2
- SDHC | c.66C>T p.L22= | Silent (SNP) | VAF 190/377 reads (50%) | catalogued as rs778965036, COSV100713632; called by muse, mutect2, varscan2
- SIM1 | c.1623G>A p.S541= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs760045551, COSV53492414; called by muse, mutect2
- SLC17A8 | c.552C>T p.C184= | Silent (SNP) | VAF 28/390 reads (7%) | catalogued as rs139101406; ClinVar: uncertain significance; called by muse, mutect2
- SLC28A2 | c.612G>A p.S204= | Silent (SNP) | VAF 75/171 reads (44%) | catalogued as rs188897314; called by muse, mutect2, varscan2
- SLC47A2 | c.1602T>C p.S534= | Silent (SNP) | VAF 80/80 reads (100%) | called by muse, mutect2, varscan2
- SLK | c.2287T>C p.L763= | Silent (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- SLX4 | c.1845C>T p.L615= | Silent (SNP) | VAF 165/321 reads (51%) | catalogued as rs1056084; ClinVar: likely benign; called by muse, mutect2, varscan2
- SOX11 | c.102G>A p.L34= | Silent (SNP) | VAF 82/166 reads (49%) | called by muse, mutect2, varscan2
- TBX18 | c.867C>T p.S289= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as rs771393702, COSV100858566, COSV63736644; called by muse, mutect2, varscan2
- TFAP2C | c.153C>T p.V51= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs767119816, COSV52371676; called by muse, mutect2, varscan2
- TMEM132C | c.195G>A p.K65= | Silent (SNP) | VAF 92/191 reads (48%) | catalogued as COSV70662213, COSV70670108; called by muse, mutect2, varscan2
- TRIM71 | c.2472C>T p.N824= | Silent (SNP) | VAF 69/148 reads (47%) | catalogued as rs747297279; called by muse, mutect2, varscan2
- UGT1A8 | c.633C>A p.I211= | Silent (SNP) | VAF 109/301 reads (36%) | called by muse, mutect2, varscan2
- VIM | c.165G>A p.S55= | Silent (SNP) | VAF 89/172 reads (52%) | catalogued as rs1408873660; called by muse, mutect2, varscan2
- VPS9D1 | c.45C>T p.S15= | Silent (SNP) | VAF 127/253 reads (50%) | called by muse, mutect2, varscan2
- ACTG1P17 | n.554A>G | RNA (SNP) | VAF 48/133 reads (36%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+1242T>C | Intron (SNP) | VAF 120/121 reads (99%) | called by muse, mutect2, varscan2
- CD8A | chr2:86790923 G>A | 5'Flank (SNP) | VAF 143/295 reads (48%) | catalogued as rs1286696703; called by muse, mutect2, varscan2
- CDC40 | c.-4del | 5'UTR (DEL) | VAF 99/227 reads (44%) | called by mutect2, pindel, varscan2
- CDH13 | c.-28C>T | 5'UTR (SNP) | VAF 145/288 reads (50%) | catalogued as rs1567568354; called by muse, mutect2, varscan2
- EPDR1 | c.269+179C>A | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, varscan2
- EYS | c.1766+2564A>C | Intron (SNP) | VAF 12/205 reads (6%) | catalogued as COSV100677181; called by muse, mutect2
- GBA3 | c.59-8514T>G | Intron (SNP) | VAF 132/418 reads (32%) | catalogued as rs538434925, COSV69742627; called by muse, varscan2
- GBA3 | c.59-8416G>A | Intron (SNP) | VAF 110/408 reads (27%) | catalogued as rs756091811, COSV69742584; called by muse, varscan2
- GBA3 | c.59-8306A>G | Intron (SNP) | VAF 75/197 reads (38%) | catalogued as rs532279707, COSV69742589; called by muse, varscan2
- GBA3 | c.59-8073T>C | Intron (SNP) | VAF 56/171 reads (33%) | catalogued as rs538774739, COSV69742631; called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1552C>T | RNA (SNP) | VAF 186/502 reads (37%) | called by muse, mutect2, varscan2
- LAMTOR4 | c.202+109G>T | Intron (SNP) | VAF 176/370 reads (48%) | called by muse, mutect2, varscan2
- LHX8 | c.18+15A>G | Intron (SNP) | VAF 136/304 reads (45%) | called by muse, mutect2, varscan2
- NBPF22P | n.355A>G | RNA (SNP) | VAF 240/515 reads (47%) | called by muse, mutect2, varscan2
- NUP43 | chr6:149746540 C>G | 5'Flank (SNP) | VAF 199/414 reads (48%) | called by muse, mutect2, varscan2
- OR3A4P | n.474C>T | RNA (SNP) | VAF 106/106 reads (100%) | catalogued as rs137875208; called by muse, mutect2, varscan2
- RUNX1T1 | c.-5G>A | 5'UTR (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
- SCN4B | c.-24G>A | 5'UTR (SNP) | VAF 42/42 reads (100%) | catalogued as rs1472148593; called by muse, mutect2
- SNORD116-14 | n.69G>A | RNA (SNP) | VAF 142/304 reads (47%) | catalogued as rs373403051; called by muse, mutect2, varscan2
- ZNF570 | chr19:37467882 T>C | 5'Flank (SNP) | VAF 91/173 reads (53%) | called by muse, mutect2, varscan2
